Somatic mutation profile of tumor specimen TCGA-CZ-5984-01A (aliquot TCGA-CZ-5984-01A-11D-1669-08) from TCGA case TCGA-CZ-5984, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.4 years (18,775 days).
Specimen TCGA-CZ-5984-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3b3df8f-c1e3-4115-8420-b1b98f832f47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5984-11A (Solid Tissue Normal), aliquot TCGA-CZ-5984-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82538e51-a1b7-41d1-8747-3f2014262cca

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50766880; called by muse, mutect2, varscan2
- ALDH3B2 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV62429369; called by muse, mutect2, varscan2
- ANXA7 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65824429; called by muse, mutect2, varscan2
- ARHGDIA | c.553_555del p.D185del | In Frame Del (DEL) | VAF 18/85 reads (21%) | catalogued as rs587776969; called by pindel, varscan2
- BMPER | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs200035524, COSV51830796; called by muse, mutect2, varscan2
- CACNA1G | c.7014C>A p.S2338R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.307); catalogued as COSV61738682; called by muse, mutect2, varscan2
- CES1 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090036; called by muse, mutect2
- CFAP74 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV54564782, COSV54573578; called by muse, mutect2, varscan2
- CFHR4 | c.1191G>T p.M397I (on ENST00000367416 / NM_001201551.2; = p.M151I on NM_006684.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.131); catalogued as COSV52235356; called by muse, mutect2, varscan2
- COL12A1 | c.3862C>A p.Q1288K | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs772151427, COSV59407418; called by muse, mutect2, varscan2
- COL5A3 | c.2680C>T p.R894* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as rs560807981, COSV53415766; called by muse, mutect2, varscan2
- COQ6 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV53180111; called by muse, mutect2, varscan2
- CSGALNACT2 | c.711dup p.K238* | Frame Shift Ins (INS) | VAF 23/160 reads (14%) | catalogued as rs1189033451; called by mutect2, pindel, varscan2
- DNAJB5 | c.826T>C p.C276R | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56627372; called by muse, mutect2, varscan2
- GLS | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV57845106; called by muse, mutect2, varscan2
- IDNK | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52892571; called by muse, mutect2, varscan2
- KDELR3 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV53249646; called by muse, mutect2, varscan2
- KIF20A | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751619840, COSV67509604; called by muse, mutect2, varscan2
- LRWD1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52962142; called by muse, mutect2, varscan2
- NPNT | c.222G>T p.K74N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59756830; called by muse, mutect2, varscan2
- PCDHB15 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV50878408; called by muse, mutect2, varscan2
- PCDHGB5 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as COSV54027060; called by muse, mutect2, varscan2
- PRKCB | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1260666109, COSV57778537; called by muse, mutect2, varscan2
- SHPRH | c.750T>A p.N250K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV51617333; called by muse, mutect2, varscan2
- SMUG1 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV54540376; called by muse, mutect2, varscan2
- ST8SIA5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 47/96 reads (49%) | PolyPhen benign (0.199); catalogued as COSV59335091; called by muse, mutect2, varscan2
- TM6SF1 | c.494C>G p.T165R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1485751218, COSV51946420; called by muse, mutect2, varscan2
- TTC7B | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60639112; called by muse, mutect2, varscan2
- WAPL | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53940041; called by muse, mutect2, varscan2
- ZNF335 | c.2351C>A p.A784D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV59820091; called by muse, mutect2, varscan2
- TOB2 | c.584del p.G195Afs*9 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- UBE2A | c.237_241+1del p.X79_splice | Splice Site (DEL) | VAF 33/69 reads (48%) | called by mutect2, pindel
- VHL | c.616dup p.I206Nfs*50 | Frame Shift Ins (INS) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- AGL | c.927G>A p.A309= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs181804327, COSV54058069, COSV99648566; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA8 | c.960G>A p.P320= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs201432613, COSV51296721; called by muse, mutect2, varscan2
- FAM207A | c.207G>A p.L69= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV52422104; called by muse, mutect2, varscan2
- GCNT1 | c.798G>T p.L266= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV65058755; called by muse, mutect2, varscan2
- PCDHA5 | c.66C>T p.Y22= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as COSV65357596; called by muse, mutect2, varscan2
- PPM1B | c.867T>C p.S289= | Silent (SNP) | VAF 53/96 reads (55%) | catalogued as COSV56769684; called by muse, mutect2, varscan2
- RAB34 | c.615C>T p.V205= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV56388689; called by muse, mutect2, varscan2
- SALL3 | c.1974G>A p.T658= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs759576604, COSV73306329; called by muse, mutect2
- SLC19A1 | c.813C>T p.S271= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV60757717; called by muse, mutect2, varscan2
- SRF | c.1368G>A p.Q456= | Silent (SNP) | VAF 67/309 reads (22%) | catalogued as COSV52734373; called by muse, mutect2, varscan2
- ZFPM2 | c.873C>A p.A291= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as rs750690965, COSV65875750; called by muse, mutect2, varscan2
